Somatic mutation profile of tumor specimen 0DPHAC from CCDI case PBCCSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Solitary fibrous tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,120 days).
Specimen 0DPHAC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13b30441-cfbf-4f13-9034-8c1ee5076c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPH9X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ba1394d-19fc-40b0-bc82-863aa8c3c695

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Intron 3, 3'UTR 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAB2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV55667244; called by muse, mutect2, varscan2
- NAB2 | c.1493G>A p.R498K | Missense Mutation (SNP) | VAF 254/674 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as rs1445050647; called by muse, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- SMCR8 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 145/404 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs779196442; called by muse, mutect2, varscan2
- TMEM74 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 191/595 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs774905434, COSV52464332; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 39/770 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 30/1022 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- ITGAM | c.3009G>T p.E1003D (on ENST00000648685 / NM_001145808.2; = p.E1002D on NM_000632.4) | Missense Mutation (SNP) | VAF 146/470 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KDR | c.3304+1G>A p.X1102_splice | Splice Site (SNP) | VAF 174/519 reads (34%) | called by muse, mutect2, varscan2
- NAB2 | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OSMR | c.2078A>G p.N693S | Missense Mutation (SNP) | VAF 118/409 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RGS7 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 108/355 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STARD9 | c.4206T>G p.S1402R | Missense Mutation (SNP) | VAF 111/363 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- STAT6 | c.2248C>G p.Q750E | Missense Mutation (SNP) | VAF 140/422 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UQCC1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 197/661 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- VPS13B | c.2233A>T p.T745S | Missense Mutation (SNP) | VAF 250/736 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EMILIN1 | c.1455C>G p.A485= | Silent (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- NFAM1 | c.138C>T p.T46= | Silent (SNP) | VAF 158/443 reads (36%) | catalogued as rs753015128; called by muse, mutect2, varscan2
- SRPK2 | c.1170C>G p.G390= | Silent (SNP) | VAF 18/548 reads (3%) | called by muse, mutect2
- STAT6 | c.2419C>T p.L807= | Silent (SNP) | VAF 166/500 reads (33%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 41/412 reads (10%) | called by muse, varscan2
- GPRC5B | chr16:19885643 C>T | 5'Flank (SNP) | VAF 4/43 reads (9%) | called by muse, varscan2
- LRRC37B | c.2781+58A>T | Intron (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- NAB2 | c.*94G>C | 3'UTR (SNP) | VAF 9/42 reads (21%) | called by muse, varscan2
- PCDHGA9 | c.2424+95A>G | Intron (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- STAT6 | c.2160-25C>T | Intron (SNP) | VAF 98/261 reads (38%) | called by muse, mutect2, varscan2
